Somatic mutation profile of tumor specimen C3L-07624-04 (aliquot CPT0452110006) from CPTAC case C3L-07624, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 60.2 years (21,988 days).
Specimen C3L-07624-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4f6ec7b-7b0e-4634-9930-12e15051f473.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07624-32 (Blood Derived Normal), aliquot CPT0452260004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/100c52aa-2cef-406f-9980-b4f631b88118

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP5Z1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 28/553 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs769661656, COSV100804291; called by muse, mutect2
- CAVIN4 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV100293145; called by muse, mutect2
- SEC14L2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 24/439 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs985161576; called by muse, mutect2
- SIGLEC10 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV59480601; called by muse, mutect2
- SLC35A1 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 19/467 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CX057623; called by muse, mutect2
- TFEB | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 15/431 reads (3%) | catalogued as rs1431016061; called by muse, mutect2
- ZFYVE26 | c.6209G>T p.G2070V | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185111099, COSV61328353; called by muse, mutect2
- ARID2 | c.2498C>G p.S833C | Missense Mutation (SNP) | VAF 11/334 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2
- CLN6 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 19/588 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- PMF1 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 20/568 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2
- SLAMF6 | c.640T>A p.C214S | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9C1 | c.1427C>A p.T476K | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.01); called by muse, mutect2
- UHRF1 | c.580A>T p.N194Y (on ENST00000612630 / NM_001290050.1; = p.N207Y on NM_013282.4) | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2
- ZMIZ1 | c.2089A>G p.K697E | Missense Mutation (SNP) | VAF 19/434 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- ACAN | c.1908C>T p.I636= | Silent (SNP) | VAF 34/661 reads (5%) | catalogued as rs746789171, COSV100719207, COSV61371563; called by muse, mutect2
- DAB1 | c.1605T>C p.D535= (on ENST00000371231; = p.D502= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 15/419 reads (4%) | called by muse, mutect2
- MYO1D | c.183C>T p.D61= | Silent (SNP) | VAF 22/488 reads (5%) | called by muse, mutect2
- RNF139 | c.1086A>C p.A362= | Silent (SNP) | VAF 20/411 reads (5%) | catalogued as rs1192268748; called by muse, mutect2
